Somatic mutation profile of tumor specimen C3L-01304-01 (aliquot CPT0064210006) from CPTAC case C3L-01304, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 68.9 years (25,175 days).
Specimen C3L-01304-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24b72b41-8707-4527-af0f-f48c4be369c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01304-31 (Blood Derived Normal), aliquot CPT0065400002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6175ab87-513d-4adf-850e-64d7d5ebc248

The open-access MAF lists 56 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 10, Nonsense Mutation 4, 5'Flank 3, Frame Shift Ins 3, Frame Shift Del 2, Intron 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 152/443 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP1B1 | c.337A>T p.I113F | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1165637636; called by muse, mutect2, varscan2
- BRINP1 | c.2008C>T p.R670C | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs1341594254, COSV56314239; called by muse, mutect2, varscan2
- COL19A1 | c.2410G>A p.G804R | Missense Mutation (SNP) | VAF 100/283 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59570355; called by muse, mutect2, varscan2
- CREBRF | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 162/218 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1355899619; called by muse, mutect2, varscan2
- FGD1 | c.1954C>T p.L652F | Missense Mutation (SNP) | VAF 71/622 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); catalogued as rs984927603; called by muse, mutect2, varscan2
- KCNA2 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433727837, COSV60369380, COSV60369854; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MLNR | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 75/477 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.557); catalogued as rs1362328067, COSV99519693; called by muse, mutect2, varscan2
- NIBAN3 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs772477270, COSV56305549; called by muse, mutect2, varscan2
- NOTCH3 | c.2659del p.D887Mfs*6 | Frame Shift Del (DEL) | VAF 95/311 reads (31%) | catalogued as COSV54627088; called by mutect2, pindel, varscan2
- OR4K13 | c.734C>A p.T245K | Missense Mutation (SNP) | VAF 127/314 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV59859444; called by muse, mutect2, varscan2
- P2RY6 | c.716G>T p.R239L | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.408); catalogued as rs569014304, COSV62936543; called by muse, mutect2, varscan2
- PCDH19 | c.269A>G p.D90G | Missense Mutation (SNP) | VAF 39/320 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as CM135068; called by muse, mutect2, varscan2
- PLXNA1 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as rs769862865, COSV52527647; called by muse, mutect2, varscan2
- RHBDF2 | c.2452G>A p.A818T | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs770206566; ClinVar: benign; called by muse, mutect2, varscan2
- RYR1 | c.7210G>A p.E2404K | Missense Mutation (SNP) | VAF 98/299 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.27); catalogued as rs111364296, CM091767; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC35F4 | c.1367G>A p.R456H (on ENST00000339762 / NM_001352015.2; = p.R420H on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/353 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769290818; called by muse, mutect2
- TMPRSS7 | c.553C>T p.R185C (on ENST00000452346; = p.R72C on NM_001042575.2) | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs769381998, COSV69981192, COSV69981536; called by muse, mutect2, varscan2
- TUBGCP6 | c.1937G>T p.R646L | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780987973; called by muse, mutect2, varscan2
- AREG | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 68/219 reads (31%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.1954A>G p.K652E | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- ARID1A | c.1562del p.Q521Rfs*98 | Frame Shift Del (DEL) | VAF 190/629 reads (30%) | called by mutect2, pindel, varscan2
- BROX | c.1150-1G>A p.X384_splice | Splice Site (SNP) | VAF 25/87 reads (29%) | called by muse, mutect2, varscan2
- CDK13 | c.2135G>T p.G712V | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CR1L | c.251G>T p.W84L | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CTNND1 | c.2012_2013dup p.L672Ffs*11 (on ENST00000399050 / NM_001085458.2; = p.L666Ffs*11 on NM_001331.3) | Frame Shift Ins (INS) | VAF 57/174 reads (33%) | called by mutect2, pindel, varscan2
- CXCR2 | c.526C>A p.L176M | Missense Mutation (SNP) | VAF 96/254 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DYNC1LI1 | c.1140+3A>G | Splice Region (SNP) | VAF 47/111 reads (42%) | called by muse, mutect2, varscan2
- ERFE | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 93/211 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM83B | c.557dup p.N186Kfs*8 | Frame Shift Ins (INS) | VAF 17/77 reads (22%) | called by mutect2, pindel, varscan2
- KIF4A | c.2866G>T p.E956* | Nonsense Mutation (SNP) | VAF 18/133 reads (14%) | called by muse, mutect2, varscan2
- METTL2B | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 87/223 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- MGAM | c.4094G>A p.G1365E | Missense Mutation (SNP) | VAF 56/434 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEFM | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 60/318 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- NMT1 | c.1443G>A p.W481* | Nonsense Mutation (SNP) | VAF 72/174 reads (41%) | called by muse, mutect2, varscan2
- NSD1 | c.4438A>T p.K1480* | Nonsense Mutation (SNP) | VAF 282/406 reads (69%) | called by muse, mutect2, varscan2
- OR4X2 | c.724T>C p.F242L | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHF8 | c.1272C>A p.H424Q (on ENST00000357988 / NM_001184896.1; = p.H388Q on NM_015107.3) | Missense Mutation (SNP) | VAF 34/432 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- PTEN | c.502_503insGTTA p.I168Sfs*13 | Frame Shift Ins (INS) | VAF 90/140 reads (64%) | called by mutect2, pindel, varscan2
- SYT5 | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZNF469 | c.7495A>G p.R2499G (on ENST00000437464; = p.R2527G on NM_001367624.2) | Missense Mutation (SNP) | VAF 50/411 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAM22 | c.459A>T p.T153= | Silent (SNP) | VAF 79/238 reads (33%) | called by muse, mutect2, varscan2
- ATP2B2 | c.3339G>A p.R1113= (on ENST00000352432; = p.R1079= on NM_001683.5) | Silent (SNP) | VAF 104/303 reads (34%) | called by muse, mutect2, varscan2
- COL6A3 | c.3861C>T p.N1287= | Silent (SNP) | VAF 189/489 reads (39%) | catalogued as rs113247852, COSV55080654, COSV55107902; ClinVar: likely benign; called by muse, mutect2, varscan2
- FGD1 | c.822C>T p.D274= | Silent (SNP) | VAF 81/211 reads (38%) | catalogued as rs762455009, COSV100911045, COSV64308558; ClinVar: likely benign; called by muse, mutect2, varscan2
- FGR | c.774C>T p.I258= | Silent (SNP) | VAF 56/175 reads (32%) | called by muse, mutect2, varscan2
- KRTAP10-3 | c.90C>A p.P30= | Silent (SNP) | VAF 58/178 reads (33%) | called by muse, mutect2
- NOBOX | c.207A>G p.K69= | Silent (SNP) | VAF 18/516 reads (3%) | called by muse, mutect2
- RIN1 | c.474G>A p.P158= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs750484575; called by muse, mutect2, varscan2
- TMEM187 | c.120C>T p.Y40= | Silent (SNP) | VAF 113/301 reads (38%) | catalogued as rs782144234, COSV64141811; called by muse, mutect2, varscan2
- ZFHX4 | c.7308G>A p.S2436= | Silent (SNP) | VAF 77/208 reads (37%) | catalogued as rs778251008, COSV50786796, COSV99263090; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502302 del TAAT | 5'Flank (DEL) | VAF 39/128 reads (30%) | called by mutect2, pindel, varscan2
- GK | c.338-3560C>A | Intron (SNP) | VAF 101/305 reads (33%) | called by muse, mutect2, varscan2
- RAD52 | c.467+268C>T | Intron (SNP) | VAF 27/214 reads (13%) | called by muse, varscan2
- SYCE1 | chr10:133568294 G>A | 5'Flank (SNP) | VAF 91/237 reads (38%) | catalogued as rs1487737070; called by muse, mutect2, varscan2
- ZNF687 | chr1:151281587 C>T | 5'Flank (SNP) | VAF 25/246 reads (10%) | catalogued as rs376617144; called by muse, mutect2, varscan2
